Somatic mutation profile of tumor specimen TARGET-10-PAPZNK-03A (aliquot TARGET-10-PAPZNK-03A-01D) from TARGET case TARGET-10-PAPZNK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.0 years (3,658 days).
Specimen TARGET-10-PAPZNK-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fab8b214-16b7-4c70-914b-3c8c72509a62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPZNK-10A (Blood Derived Normal), aliquot TARGET-10-PAPZNK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34dbdfc6-29d1-42ac-ac6e-79822be62840

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX4 | c.1894G>A p.G632S | Missense Mutation (SNP) | VAF 42/586 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61757848; called by muse, mutect2
- FNDC1 | c.5540C>T p.S1847F | Missense Mutation (SNP) | VAF 145/311 reads (47%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.889); catalogued as COSV51945002; called by muse, mutect2, varscan2
- GSE1 | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs868139791, COSV53675254, COSV53677019; called by muse, mutect2, varscan2
- KDM5C | c.3401G>A p.G1134E | Missense Mutation (SNP) | VAF 54/83 reads (65%) | SIFT tolerated (0.44); PolyPhen benign (0.034); catalogued as COSV64771241; called by muse, mutect2, varscan2
- KPNB1 | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 99/202 reads (49%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs773762133, COSV51601342; called by muse, mutect2, varscan2
- PCDHAC1 | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV53861906; called by muse, mutect2, varscan2
- PRND | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV59897534; called by muse, mutect2, varscan2
- SPINK5 | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 132/281 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs184189005, COSV56264325; called by muse, mutect2, varscan2
- SPSB3 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs746833455, COSV51603344; called by muse, mutect2, varscan2
- TRPC3 | c.724C>T p.H242Y (on ENST00000379645 / NM_001366479.2; = p.H169Y on NM_003305.2) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53383224; called by muse, mutect2, varscan2
- DEPDC5 | c.1436_1444delinsGG p.T479Rfs*36 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | called by pindel, varscan2*
- POTEH | c.1090C>A p.Q364K | Missense Mutation (SNP) | VAF 58/378 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); called by mutect2, varscan2
- GABRB3 | c.1407G>A p.L469= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs776346710, COSV54688698; called by muse, mutect2, varscan2
- NTRK2 | c.2400C>T p.I800= (on ENST00000323115 / NM_001369534.1; = p.I816= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV52887773; called by muse, mutect2, varscan2
- ZBTB4 | c.93C>T p.D31= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs773315724; called by muse, mutect2, varscan2
